Somatic mutation profile of tumor specimen ALCH-B46U-TTP1-A (aliquot ALCH-B46U-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B46U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,785 days).
Specimen ALCH-B46U-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad8f2881-1274-4a23-aab9-61807d10a148.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B46U-NB1-A (Blood Derived Normal), aliquot ALCH-B46U-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a07ca83-1060-4c67-9bf6-6ba4c07f4c93

The open-access MAF lists 307 somatic variants for this specimen: 221 protein-altering or splice-affecting, 49 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 49, Intron 18, Nonsense Mutation 10, Splice Site 9, 5'UTR 6, RNA 6, 3'UTR 4, Frame Shift Del 3, Splice Region 2, 5'Flank 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 135/426 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A1CF | c.1196G>A p.R399H (on ENST00000373993 / NM_138932.2; = p.R391H on NM_014576.4) | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs149597685; called by muse, mutect2, varscan2
- ABCC4 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs1415176622; called by muse, mutect2
- ADAM15 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665305; called by muse, mutect2
- AMY2A | c.662A>T p.D221V | Missense Mutation (SNP) | VAF 111/789 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765956745; called by muse, mutect2, varscan2
- ATRNL1 | c.1479C>A p.N493K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs782771294; called by muse, mutect2
- BDP1 | c.2119C>T p.R707* | Nonsense Mutation (SNP) | VAF 19/174 reads (11%) | catalogued as rs771638951; called by muse, mutect2, varscan2
- BLCAP | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 74/551 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1249533741; called by muse, mutect2, varscan2
- CCDC88A | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55066144; called by muse, mutect2, varscan2
- CEP350 | c.7540C>T p.R2514* | Nonsense Mutation (SNP) | VAF 16/365 reads (4%) | catalogued as COSV62599608; called by muse, mutect2
- COL11A1 | c.1999-1G>T p.X667_splice | Splice Site (SNP) | VAF 17/299 reads (6%) | catalogued as COSV62172611, COSV62179077, COSV62198366; called by muse, mutect2
- CPT1C | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs376513063; called by muse, mutect2
- CRISP2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1415839189, COSV59257194; called by muse, mutect2
- CSMD3 | c.3113C>T p.S1038L (on ENST00000297405 / NM_001363185.1; = p.S934L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as COSV99838696; called by muse, mutect2
- CSN2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs778238023; called by muse, mutect2, varscan2
- CYP26C1 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs1238867546, COSV53653236; called by muse, mutect2, varscan2
- DBX1 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 97/832 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57053590; called by muse, mutect2, varscan2
- DGKK | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs1557226570, COSV101052935; called by muse, mutect2
- FBN2 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99326385; called by muse, mutect2
- FLG2 | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 46/624 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs759032018; called by muse, mutect2
- GJA1 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs756914391, CM073090; called by muse, mutect2, varscan2
- GLA | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as CD056456; called by muse, mutect2, varscan2
- GRID1 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as rs1200006159; called by muse, varscan2
- HAS2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391691, COSV58267637; called by muse, mutect2
- HIC2 | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 119/797 reads (15%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.968); catalogued as COSV68041761; called by muse, mutect2, varscan2
- IDH3G | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1557069512, COSV99473333; called by muse, mutect2
- KCNC1 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56398866; called by muse, mutect2, varscan2
- KCNG3 | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60151507; called by muse, mutect2
- KMO | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV63810891; called by muse, mutect2
- MRI1 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs868748550; called by muse, mutect2, varscan2
- MXRA5 | c.6579-1G>C p.X2193_splice | Splice Site (SNP) | VAF 12/125 reads (10%) | catalogued as rs770763440; called by muse, mutect2
- NAT10 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57662171; called by muse, mutect2, varscan2
- NCAM2 | c.842G>T p.C281F | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522281; called by muse, mutect2
- NFE2L1 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 71/622 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62583190; called by muse, mutect2, varscan2
- OLFM2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV53431711; called by muse, mutect2, varscan2
- OR10K2 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 51/468 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100149470; called by muse, mutect2, varscan2
- OR51F1 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1478041916; called by muse, mutect2, varscan2
- OR51I1 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV100972018; called by muse, mutect2
- OR5B17 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs774932981; called by muse, mutect2, varscan2
- OR6X1 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.265); catalogued as rs754883550; called by muse, mutect2
- P2RY10 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV50685195; called by muse, varscan2
- PCDH18 | c.3176G>A p.S1059N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373972822; called by muse, mutect2, varscan2
- PCDHB3 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 76/646 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.326); catalogued as COSV50611441; called by muse, mutect2, varscan2
- PDE10A | c.346+1G>T p.X116_splice | Splice Site (SNP) | VAF 6/68 reads (9%) | catalogued as COSV63108071; called by muse, mutect2
- PHEX | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV65074225; called by muse, mutect2
- POU3F4 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 66/1462 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV100937194; called by muse, mutect2
- REPS2 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58186793; called by muse, mutect2
- RFX4 | c.712C>T p.H238Y (on ENST00000392842 / NM_213594.3; = p.H144Y on NM_032491.6) | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV57574598; called by muse, mutect2
- RGPD4 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558792394; called by muse, varscan2
- SATB1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100113397; called by muse, mutect2
- SCN7A | c.4712G>A p.R1571K | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.928); catalogued as COSV69270078; called by muse, mutect2
- SCUBE1 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904493134, COSV62612504; called by muse, mutect2, varscan2
- SIN3B | c.2153A>T p.D718V | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99931886; called by muse, mutect2, varscan2
- SLC25A52 | c.702G>T p.M234I (on ENST00000672005; = p.M224I on NM_001034172.4) | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV52503215; called by muse, mutect2
- SMAD5 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs757899882; called by muse, mutect2
- SPEG | c.8099C>A p.P2700Q | Missense Mutation (SNP) | VAF 75/614 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56666936; called by muse, mutect2, varscan2
- STX4 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs562489469, COSV58268799; called by muse, mutect2, varscan2
- TENM4 | c.8095G>A p.V2699M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs533363061, COSV53674433; called by muse, mutect2
- TMEM225 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as COSV66693732; called by muse, mutect2, varscan2
- TMOD3 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs753349972; called by mutect2, varscan2
- TRANK1 | c.2976G>T p.M992I | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV57166228; called by muse, mutect2
- UGDH | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57097646; called by muse, mutect2
- UNCX | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs752538020; called by muse, mutect2, varscan2
- ABLIM3 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AC131160.1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- ADAMTS4 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADGRA1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- AFF2 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- AKAP10 | c.1079_1080insA p.R361Afs*7 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel*
- ARHGAP21 | c.3318G>C p.R1106S | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BABAM1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- BIN2 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BMPER | c.936G>C p.E312D | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- C11orf80 | c.1601-1G>C p.X534_splice | Splice Site (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2
- C8orf76 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- C9orf135 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CA9 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- CACNA1E | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CCDC168 | c.8779G>A p.E2927K | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.111); called by muse, mutect2
- CCDC33 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 64/517 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC89 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 80/421 reads (19%) | called by muse, mutect2, varscan2
- CCDC92 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 34/645 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.391); called by muse, mutect2
- CDH10 | c.2172C>A p.D724E | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDK6 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 51/477 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDX4 | c.196T>A p.W66R | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- CELSR2 | c.3652G>T p.A1218S | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.079); called by muse, mutect2
- CERS6 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHTF18 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 23/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CILK1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CLEC4F | c.1228T>A p.L410I | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLHC1 | c.1384+1G>T p.X462_splice | Splice Site (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2
- CLSTN2 | c.2503G>T p.V835L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- CMKLR1 | c.481A>T p.M161L (on ENST00000312143 / NM_001142344.2; = p.M159L on NM_004072.3) | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL17A1 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 85/830 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.7520G>T p.C2507F (on ENST00000312481; = p.C2503F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.4432C>A p.P1478T | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CPAMD8 | c.1786G>T p.V596L (on ENST00000651564; = p.V549L on NM_015692.5) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2
- CPEB4 | c.763A>C p.S255R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CYRIA | c.104G>C p.W35S | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DDN | c.806C>A p.T269K | Missense Mutation (SNP) | VAF 104/450 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DLG3 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DNAAF6 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.314); called by muse, mutect2
- DNAH3 | c.5173G>A p.A1725T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.276); called by mutect2, varscan2
- DRD5 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 81/469 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC2H1 | c.1894A>T p.I632F | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EOMES | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- EPS8L3 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN2 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXW7 | c.682G>C p.V228L (on ENST00000281708 / NM_001349798.2; = p.V148L on NM_018315.5) | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- FTHL17 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.133); called by muse, mutect2
- G6PD | c.1364G>C p.S455T | Missense Mutation (SNP) | VAF 90/679 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GGT6 | c.1280C>G p.A427G (on ENST00000574154 / NM_001122890.3; = p.A395G on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- GHRL | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L7 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.341); called by muse, mutect2
- GOLGA8B | c.1768G>T p.V590L | Missense Mutation (SNP) | VAF 137/1516 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GPR1 | c.865T>A p.S289T | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); called by muse, mutect2
- GRM6 | c.1373T>A p.V458E | Missense Mutation (SNP) | VAF 97/577 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GRM7 | c.1063C>A p.L355I | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- HMBS | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 69/680 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HOXB4 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 35/499 reads (7%) | called by muse, mutect2
- HPS5 | c.3327G>C p.Q1109H (on ENST00000349215 / NM_181507.2; = p.Q995H on NM_007216.4) | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRNR | c.3125C>A p.S1042Y | Missense Mutation (SNP) | VAF 359/2751 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HSPA12B | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); called by muse, mutect2
- IGKV2D-24 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 44/499 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGSF1 | c.3311A>T p.Q1104L | Missense Mutation (SNP) | VAF 17/412 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- IQSEC3 | c.2527G>T p.E843* (on ENST00000538872 / NM_001170738.2; = p.E540* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 39/249 reads (16%) | called by muse, mutect2, varscan2
- ITGA1 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.239); called by muse, mutect2
- ITIH6 | c.2070G>T p.L690F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- IWS1 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- KCNC2 | c.806G>T p.S269I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNG1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- KIAA1109 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KPNB1 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); called by mutect2, varscan2
- KRT14 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 50/1142 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2
- LAMA2 | c.2918G>T p.G973V | Missense Mutation (SNP) | VAF 108/772 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEL2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- MAP3K14 | c.674A>T p.E225V | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- MGAT4B | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 71/569 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MGAT5 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- MMS19 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- MUC16 | c.6041C>A p.P2014H | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYO15A | c.6392T>G p.L2131R | Missense Mutation (SNP) | VAF 62/483 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MYOCD | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX2-4 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 134/890 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX6-2 | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NLK | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- NLRP10 | c.1784A>G p.K595R | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.164); called by muse, mutect2
- NSDHL | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2
- OR2AG1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR2C1 | c.86T>A p.I29K | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR2M3 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4A5 | c.286A>T p.M96L | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); called by muse, mutect2
- OR5H2 | c.84del p.W28* | Frame Shift Del (DEL) | VAF 34/346 reads (10%) | called by mutect2, pindel, varscan2
- OSBP2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PANK4 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- PCDHA5 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 15/400 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.406); called by muse, mutect2
- PCDHB4 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2
- PDZRN3 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF8 | c.15C>A p.R5= | Splice Region (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PITRM1 | c.1150A>T p.T384S | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2
- PKD1L3 | c.1979G>T p.R660M | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PLEKHM2 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIP5K2 | c.1659T>A p.H553Q | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM9 | c.509-2A>G p.X170_splice | Splice Site (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.1637C>A p.S546Y | Missense Mutation (SNP) | VAF 56/600 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.4); called by muse, mutect2
- PSME2 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- PZP | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- REG1B | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNASE9 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.447); called by muse, mutect2
- RNF113A | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2
- RNF148 | c.329G>C p.C110S | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RORC | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RPL27 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS5 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2
- RPS6KA6 | c.1350G>T p.M450I | Missense Mutation (SNP) | VAF 21/666 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- RSC1A1 | c.56A>T p.Q19L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SAGE1 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by muse, varscan2
- SCN4A | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 98/994 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SCYL2 | c.2088_2097del p.K697Sfs*20 | Frame Shift Del (DEL) | VAF 81/320 reads (25%) | called by mutect2, pindel, varscan2
- SEC24B | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEH1L | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6A | c.2948T>C p.V983A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- SERINC3 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SETD2 | c.6409C>T p.Q2137* | Nonsense Mutation (SNP) | VAF 36/357 reads (10%) | called by muse, varscan2
- SEZ6 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SHROOM2 | c.2317G>A p.G773S | Missense Mutation (SNP) | VAF 61/596 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L1 | c.1699_1700del p.G567Pfs*13 | Frame Shift Del (DEL) | VAF 9/104 reads (9%) | called by mutect2, pindel
- SLIT3 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by mutect2, varscan2
- SMC3 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SP8 | c.59C>T p.S20L (on ENST00000361443 / NM_198956.4; = p.S38L on NM_182700.6) | Missense Mutation (SNP) | VAF 109/1040 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SPATA48 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPTB | c.3049G>T p.E1017* | Nonsense Mutation (SNP) | VAF 36/438 reads (8%) | called by muse, mutect2
- ST8SIA2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 38/415 reads (9%) | PolyPhen possibly damaging (0.627); called by muse, mutect2
- STARD9 | c.9271G>A p.E3091K | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TAOK1 | c.307-2A>T p.X103_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- TC2N | c.1377A>C p.E459D | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, varscan2
- TCERG1L | c.671-1G>T p.X224_splice | Splice Site (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- TECPR2 | c.1142A>T p.E381V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- TECTA | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TFE3 | c.575A>C p.Q192P | Missense Mutation (SNP) | VAF 64/488 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- TFG | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 53/461 reads (11%) | called by muse, mutect2, varscan2
- THPO | c.1150C>T p.P384S (on ENST00000649095 / NM_001290003.1; = p.P244S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.45); called by muse, mutect2
- TMEM131L | c.2923C>G p.Q975E | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- TMEM80 | c.262_270del p.X88_splice (on ENST00000526170 / NM_001276274.1; = p.X150_splice on NM_174940.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 10/95 reads (11%) | called by pindel, varscan2
- TSHZ1 | c.1719G>T p.W573C (on ENST00000580243 / NM_001308210.2; = p.W528C on NM_005786.6) | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSPYL6 | c.886T>A p.F296I | Missense Mutation (SNP) | VAF 24/780 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TTLL10 | c.892G>C p.E298Q (on ENST00000379289 / NM_001130045.2; = p.E225Q on NM_153254.3) | Missense Mutation (SNP) | VAF 65/572 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- UNC80 | c.4695G>T p.V1565= | Splice Region (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- UQCRFS1 | c.16_39del p.S6_P13del | In Frame Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- USP13 | c.2102A>T p.E701V | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.145); called by muse, mutect2
- USP9X | c.2924G>T p.S975I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP9X | c.6932C>T p.P2311L | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- UTRN | c.8302C>G p.L2768V | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- XKR4 | c.1190T>C p.F397S | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YY2 | c.94A>G p.M32V | Missense Mutation (SNP) | VAF 39/517 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZBTB33 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ZDBF2 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2
- ZNF492 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF613 | c.579G>T p.K193N (on ENST00000293471 / NM_001031721.4; = p.K157N on NM_024840.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2
- ZNF646 | c.3224A>T p.Q1075L | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ZSCAN29 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); called by muse, mutect2
- ABLIM3 | c.1176C>A p.S392= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV100448767; called by muse, mutect2
- ADCK2 | c.276C>T p.G92= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as rs560294528; called by muse, mutect2, varscan2
- ANKRD54 | c.735G>A p.L245= | Silent (SNP) | VAF 54/435 reads (12%) | catalogued as rs771139290; called by muse, mutect2, varscan2
- AP3M1 | c.225A>T p.P75= | Silent (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- ARFGAP1 | c.1098G>T p.V366= | Silent (SNP) | VAF 74/408 reads (18%) | called by muse, mutect2, varscan2
- ASH1L | c.5976A>G p.A1992= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- CACNG4 | c.42G>T p.T14= | Silent (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- CDK11A | c.1167G>T p.L389= (on ENST00000378633 / NM_001313896.2; = p.L386= on NM_024011.4) | Silent (SNP) | VAF 68/840 reads (8%) | called by muse, mutect2
- CFP | c.603C>A p.P201= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- CNTN2 | c.1212C>A p.I404= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as COSV59353308; called by muse, mutect2
- CPXM2 | c.975C>A p.R325= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- DST | c.16500G>T p.S5500= (on ENST00000361203 / NM_001374722.1; = p.S3088= on NM_015548.5) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs780435915; called by muse, mutect2, varscan2
- DTX1 | c.183C>A p.V61= | Silent (SNP) | VAF 95/445 reads (21%) | called by muse, mutect2, varscan2
- EGFL7 | c.546C>T p.P182= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- FBN2 | c.2061C>A p.G687= | Silent (SNP) | VAF 69/414 reads (17%) | called by muse, mutect2, varscan2
- FLG2 | c.2472G>T p.G824= | Silent (SNP) | VAF 48/626 reads (8%) | catalogued as rs774329489; called by muse, mutect2
- FTCD | c.570C>G p.L190= | Silent (SNP) | VAF 58/578 reads (10%) | called by muse, mutect2
- GABRE | c.957C>T p.T319= | Silent (SNP) | VAF 15/310 reads (5%) | called by muse, mutect2
- HEPH | c.1662G>T p.V554= (on ENST00000343002; = p.V287= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/452 reads (4%) | called by muse, mutect2
- HNRNPD | c.195G>T p.G65= | Silent (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- HTR2A | c.444T>C p.C148= | Silent (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- IL21 | c.159G>C p.V53= | Silent (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- JAGN1 | c.114G>A p.K38= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100314713; called by muse, mutect2
- KCNV2 | c.990C>T p.F330= | Silent (SNP) | VAF 153/878 reads (17%) | catalogued as rs773388753, COSV66057256, COSV66058001; called by muse, mutect2, varscan2
- LIG1 | c.2031G>T p.R677= | Silent (SNP) | VAF 71/414 reads (17%) | called by muse, mutect2, varscan2
- LOXHD1 | c.2073G>A p.K691= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- LPA | c.42G>C p.L14= | Silent (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- MMP14 | c.1458C>T p.F486= | Silent (SNP) | VAF 24/796 reads (3%) | called by muse, mutect2
- MST1R | c.750G>T p.V250= | Silent (SNP) | VAF 48/494 reads (10%) | catalogued as COSV56569643; called by muse, mutect2
- MYORG | c.1116C>T p.N372= | Silent (SNP) | VAF 49/244 reads (20%) | catalogued as rs773122688, COSV52628224; called by muse, mutect2, varscan2
- NKD2 | c.492C>A p.G164= | Silent (SNP) | VAF 66/708 reads (9%) | called by muse, mutect2
- NKX2-2 | c.318C>A p.P106= | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- NUP42 | c.300C>T p.N100= | Silent (SNP) | VAF 26/238 reads (11%) | catalogued as rs373363122; called by muse, varscan2
- OR4C46 | c.138C>A p.T46= | Silent (SNP) | VAF 27/487 reads (6%) | called by muse, mutect2
- PCDHB10 | c.1299C>A p.T433= | Silent (SNP) | VAF 283/1912 reads (15%) | catalogued as rs1335486583; called by muse, mutect2, varscan2
- PDE8B | c.801C>T p.A267= | Silent (SNP) | VAF 37/331 reads (11%) | called by muse, mutect2, varscan2
- PIK3CG | c.2805C>T p.Y935= | Silent (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- RPS19 | c.66C>G p.L22= | Silent (SNP) | VAF 42/478 reads (9%) | called by muse, mutect2
- SDHA | c.1845G>A p.K615= | Silent (SNP) | VAF 90/1099 reads (8%) | called by muse, mutect2
- SEMA5A | c.957G>C p.V319= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- SETD1B | c.2859G>T p.L953= | Silent (SNP) | VAF 104/457 reads (23%) | catalogued as rs1391358569; called by muse, mutect2, varscan2
- SHMT2 | c.633G>A p.L211= | Silent (SNP) | VAF 25/744 reads (3%) | called by muse, mutect2
- SLC30A2 | c.378G>A p.G126= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs1408514797; called by muse, mutect2, varscan2
- SLC4A9 | c.1455C>T p.F485= (on ENST00000507527 / NM_001258428.2; = p.F461= on NM_031467.3) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV50196444; called by muse, mutect2
- SLC6A11 | c.807G>A p.L269= | Silent (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- THNSL2 | c.636C>T p.V212= | Silent (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- TNFAIP1 | c.339C>T p.I113= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as rs1404851494; called by muse, mutect2
- TRAK2 | c.282C>T p.Y94= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- URB2 | c.2364G>T p.L788= | Silent (SNP) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- ABCC8 | c.148+10C>T | Intron (SNP) | VAF 50/243 reads (21%) | called by muse, mutect2, varscan2
- AC079154.1 | n.886G>T | RNA (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- AQP12A | chr2:240687810 G>A | 5'Flank (SNP) | VAF 63/687 reads (9%) | catalogued as rs756407094; called by muse, mutect2
- CD300LG | c.-4C>A | 5'UTR (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- FADS1 | c.684+642G>T | Intron (SNP) | VAF 28/168 reads (17%) | called by muse, varscan2
- FAM90A20P | n.169A>T | RNA (SNP) | VAF 45/1917 reads (2%) | called by muse, mutect2
- FCRL5 | c.*28C>A | 3'UTR (SNP) | VAF 16/347 reads (5%) | called by muse, mutect2
- FLAD1 | c.1555-107G>C | Intron (SNP) | VAF 12/376 reads (3%) | catalogued as rs1038967436; called by muse, mutect2
- FXYD5 | c.-15C>T | 5'UTR (SNP) | VAF 22/298 reads (7%) | catalogued as rs767051949; called by muse, mutect2
- GABRG3 | c.-6G>C | 5'UTR (SNP) | VAF 14/170 reads (8%) | catalogued as COSV61530555; called by muse, mutect2
- GAD1 | c.83-49del | Intron (DEL) | VAF 53/482 reads (11%) | called by mutect2, pindel, varscan2
- GDAP1L1 | c.*258C>T | 3'UTR (SNP) | VAF 34/225 reads (15%) | catalogued as rs755560832, COSV100697567; called by muse, mutect2, varscan2
- GFOD1 | c.*3967G>C | 3'UTR (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- HIKESHI | c.269-10838A>T | Intron (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- IRX4 | c.408-252G>A | Intron (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- KDM6A | c.161+24G>A | Intron (SNP) | VAF 19/117 reads (16%) | catalogued as rs1178742270; called by muse, mutect2, varscan2
- KIRREL1 | c.*1880G>T | 3'UTR (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- LIG1 | c.1088-11C>T | Intron (SNP) | VAF 14/154 reads (9%) | catalogued as rs767345071; called by muse, mutect2
- LMO4 | chr1:87348713 T>A | 3'Flank (SNP) | VAF 28/214 reads (13%) | called by muse, varscan2
- MGAM | c.4619-12489G>T | Intron (SNP) | VAF 89/581 reads (15%) | called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.612C>T | RNA (SNP) | VAF 83/627 reads (13%) | catalogued as rs565494161; called by muse, mutect2, varscan2
- NAMPTP1 | n.127T>A | RNA (SNP) | VAF 90/748 reads (12%) | called by muse, mutect2, varscan2
- NFATC1 | c.127+3977C>T | Intron (SNP) | VAF 12/43 reads (28%) | called by mutect2, varscan2
- PIGG | c.-1G>C | 5'UTR (SNP) | VAF 57/532 reads (11%) | catalogued as rs782195633; called by muse, mutect2
- POLR3GL | c.-3A>G | 5'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.270+14G>A | Intron (SNP) | VAF 50/216 reads (23%) | catalogued as rs201002281; called by muse, mutect2
- RNF5P1 | n.231G>A | RNA (SNP) | VAF 108/696 reads (16%) | called by muse, mutect2, varscan2
- SENP6 | c.-1G>C | 5'UTR (SNP) | VAF 32/366 reads (9%) | called by muse, mutect2
- SERPINA13P | n.961C>T | RNA (SNP) | VAF 48/463 reads (10%) | catalogued as rs542864379; called by muse, mutect2, varscan2
- SRPK3 | chrX:153780466 C>G | 5'Flank (SNP) | VAF 35/295 reads (12%) | called by muse, mutect2, varscan2
- TPM3 | c.244-6766G>C | Intron (SNP) | VAF 82/936 reads (9%) | called by muse, mutect2
- TSC2 | c.600-20G>A | Intron (SNP) | VAF 46/1188 reads (4%) | called by muse, mutect2
- TSPYL2 | c.1239-38C>A | Intron (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2
- TUBE1 | c.448+40G>C | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- Z82195.2 | n.416-19572G>A | Intron (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- ZMYM5 | c.1038+65A>G | Intron (SNP) | VAF 12/118 reads (10%) | catalogued as rs371329902; called by muse, mutect2
- ZNF571 | c.9+15C>G | Intron (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
